Gene-level copy-number profile of tumor specimen C3N-03061-01 (profiled together with C3N-03061-02) from CPTAC case C3N-03061, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 62.9 years (22,974 days).
Specimen C3N-03061-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9becd5c7-4001-453f-81f4-4a4f48f555dd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03061-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/b4823cd7-876c-4637-acfe-f4b012dc9f07

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 134; copy number 1: 23,810; copy number 2: 24,859; copy number 3: 7,965; copy number 4: 1,257; copy number 5: 12; copy number 6: 307; copy number 9: 60.

Homozygous deletions (total copy number 0; autosomes only): 134 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:1,730,070–3,057,959, 9 genes (within-gene range 0–1): RPL23AP39, RPL21P17, AC018814.1, RN7SKP144, CNTN4, CNTN4-AS2, AC087427.1, HINT2P1, DNAJC19P4.
- chr3:84,638,405–89,590,097, 42 genes: LINC00971, AC117482.1, LINC02025, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6.
- chr3:191,425,493–191,591,097, 2 genes: AC073365.1, PYDC2.
- chr9:21,135,598–23,438,700, 56 genes: AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr10:50,736,078–50,816,495, 2 genes (within-gene range 0–1): AL589794.2, ASAH2B.
- chr18:77,249,848–79,002,677, 20 genes: GALR1, AC124254.2, AC124254.1, BDP1P, AC123786.1, AC123786.2, RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1, AC087399.1, AC012572.1, Y_RNA, AC044873.1, AC091027.2, AC091027.1, AC091027.3, LINC01896, SALL3.
- chr18:79,085,134–79,146,918, 3 genes (within-gene range 0–2): AC099689.3, AC125437.1, AC125437.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 379 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:22,056,587–22,439,033, 12 genes, copy number 5: ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4.
- chr18:45,034–15,330,282, 367 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 21,501. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
